Gene-level copy-number profile of tumor specimen TCGA-AA-3518-01A from TCGA case TCGA-AA-3518, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 81.5 years (29,769 days).
Specimen TCGA-AA-3518-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.74998070-95f3-486a-ade4-0e15c959617c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3518-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1af7aaae-063b-4e21-be00-32aa343aa84a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 200; copy number 2: 58,893; copy number 3: 700.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-3518-01): tumor purity 0.4, ploidy 2, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:100,375,700–101,582,128, 10 genes: AC113385.3, AC113385.2, AC113385.1, AC021086.1, FAM174A, AC027315.1, RN7SKP62, ST8SIA4, MIR548P, RN7SL802P.
- chr5:135,033,280–135,358,219, 1 gene (within-gene range 0–2): C5orf66.
- chr5:135,120,526–135,399,914, 4 genes (within-gene range 0–2): AC008406.2, AC008406.1, C5orf66-AS2, MACROH2A1.
- chr16:6,037,210–6,092,954, 2 genes: AC009135.2, AC009135.1.
- chr16:6,573,767–6,748,969, 4 genes: AC007223.1, AC007012.2, AC007012.1, RNU7-99P.
- chr16:78,793,584–78,899,644, 5 genes: AC009141.1, RPS3P7, AC136603.1, AC027279.4, AC027279.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 200. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
